Somatic mutation profile of tumor specimen MP2PRT-PARAJY-TMP1-A (aliquot MP2PRT-PARAJY-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARAJY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (862 days).
Specimen MP2PRT-PARAJY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4f90d07-c03a-491b-a859-8cb187044922.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARAJY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARAJY-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3da6219-6f19-43a3-828b-f77b0c90f4aa

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 6, Silent 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 111/222 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- CHODL | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 59/742 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1229175985; called by muse, mutect2
- HNF1A | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 288/544 reads (53%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as CD083323, CM1414600, CM971449; called by muse, mutect2, varscan2
- PXDNL | c.4109C>T p.A1370V | Missense Mutation (SNP) | VAF 116/452 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs769579619, COSV100684910, COSV62477078, COSV62496975; called by muse, mutect2, varscan2
- HUNK | c.1173+1dup | Frame Shift Ins (INS) | VAF 109/370 reads (29%) | called by mutect2, pindel, varscan2
- KIAA1210 | c.777G>C p.Q259H | Missense Mutation (SNP) | VAF 107/209 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SMG6 | c.539A>T p.D180V | Missense Mutation (SNP) | VAF 203/660 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANK3 | c.4632G>A p.S1544= | Silent (SNP) | VAF 28/242 reads (12%) | catalogued as rs146324308; called by muse, mutect2, varscan2
- CCDC110 | c.900C>T p.D300= | Silent (SNP) | VAF 90/315 reads (29%) | catalogued as rs770507320, COSV56871446; called by muse, mutect2, varscan2
- FMN2 | c.3012C>T p.P1004= | Silent (SNP) | VAF 33/266 reads (12%) | catalogued as rs1335213498, COSV60416996; called by muse, mutect2, varscan2
- OTOG | c.1887C>T p.Y629= | Silent (SNP) | VAF 176/388 reads (45%) | catalogued as rs759196357; called by muse, mutect2, varscan2
